Somatic mutation profile of tumor specimen TCGA-AZ-5403-01A (aliquot TCGA-AZ-5403-01A-01D-1650-10) from TCGA case TCGA-AZ-5403, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage II; Age at diagnosis: 43.8 years (15,983 days).
Specimen TCGA-AZ-5403-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce2ed76e-5548-4b9a-8d5b-ef87f6461bc3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AZ-5403-10A (Blood Derived Normal), aliquot TCGA-AZ-5403-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e128f60-8e0a-41b4-8993-9edac118c4e4

The open-access MAF lists 78 somatic variants for this specimen: 58 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 17, Nonsense Mutation 5, Splice Site 4, Intron 2, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDH19 | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 29/50 reads (58%) | catalogued as rs769967221, CM1211675, COSV55257472; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.559+1G>A p.X187_splice | Splice Site (SNP) | VAF 27/63 reads (43%) | hotspot (GDC flag); catalogued as rs1131691042, CS137624, COSV52670017, COSV52686439, COSV52695669; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.6655G>A p.G2219S (on ENST00000614293; = p.G2189S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368969710; called by muse, mutect2, varscan2
- ANP32B | c.179T>G p.L60R | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59585930; called by muse, mutect2
- ARFGEF1 | c.2183C>A p.T728N | Missense Mutation (SNP) | VAF 56/612 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV51601915, COSV99142856; called by muse, mutect2
- ATN1 | c.2143C>T p.P715S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.151); catalogued as rs1555143974, COSV100755946; called by muse, mutect2
- CSMD1 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs368828677, COSV68203237; called by muse, mutect2, varscan2
- DAPK1 | c.2770A>T p.I924F | Missense Mutation (SNP) | VAF 24/361 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV100802632; called by muse, mutect2
- DBNL | c.176G>A p.S59N | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as COSV68880077; called by muse, mutect2, varscan2
- DLGAP4 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as COSV100211547; called by muse, mutect2, varscan2
- ECT2L | c.807G>T p.K269N | Missense Mutation (SNP) | VAF 63/200 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV62882563; called by muse, mutect2, varscan2
- FLT1 | c.3655T>A p.F1219I | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV56716871; called by muse, mutect2, varscan2
- FREM2 | c.973A>T p.M325L | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV54827241; called by muse, mutect2, varscan2
- FRMPD2 | c.2314G>T p.E772* | Nonsense Mutation (SNP) | VAF 55/161 reads (34%) | catalogued as COSV59714786, COSV59719823; called by muse, mutect2, varscan2
- GABRB2 | c.1508A>G p.N503S (on ENST00000274547; = p.N465S on NM_000813.3) | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99196486; called by muse, mutect2, varscan2
- GRIK3 | c.1937C>T p.T646M | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1277838021, COSV66135068; called by muse, mutect2, varscan2
- HACE1 | c.2213C>T p.A738V | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.469); catalogued as rs374813736; called by muse, mutect2, varscan2
- IFIH1 | c.2313A>C p.Q771H | Missense Mutation (SNP) | VAF 81/584 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55124387; called by muse, mutect2, varscan2
- ITIH3 | c.2127C>G p.Y709* | Nonsense Mutation (SNP) | VAF 9/79 reads (11%) | catalogued as COSV101407116; called by muse, mutect2, varscan2
- KALRN | c.7753G>A p.V2585M (on ENST00000360013 / NM_001024660.4; = p.V888M on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373744782, COSV52248952; called by muse, mutect2, varscan2
- KATNIP | c.3086G>A p.R1029H | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs369563369; called by muse, mutect2, varscan2
- LAMTOR2 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 49/159 reads (31%) | catalogued as rs754521055, COSV63107492; called by muse, mutect2, varscan2
- LONP1 | c.2036G>A p.R679H | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs549574673, CM156333, COSV61501561; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LVRN | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100773640; called by muse, mutect2, varscan2
- MAPK10 | c.256A>T p.I86F (on ENST00000359221 / NM_001351625.2; = p.I124F on NM_002753.5) | Missense Mutation (SNP) | VAF 37/300 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60374967; called by muse, mutect2, varscan2
- MGAT5 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs778408120, COSV56093344; called by muse, mutect2, varscan2
- MYOM2 | c.517C>G p.L173V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50757739; called by muse, mutect2
- NAV3 | c.2133-1G>A p.X711_splice | Splice Site (SNP) | VAF 55/116 reads (47%) | catalogued as COSV57059619; called by muse, mutect2, varscan2
- NEB | c.19174C>T p.R6392C | Missense Mutation (SNP) | VAF 81/260 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs748561855, COSV50806444; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NINL | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs200992599, COSV53998163; called by muse, mutect2, varscan2
- OR5W2 | c.94T>G p.L32V | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV60614714, COSV60614862; called by muse, mutect2
- PAX9 | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64061116; called by muse, mutect2, varscan2
- PHAX | c.435A>T p.R145S | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV52549839; called by muse, mutect2, varscan2
- POLQ | c.3887G>A p.G1296D | Missense Mutation (SNP) | VAF 98/294 reads (33%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.001); catalogued as COSV99952805; called by muse, mutect2, varscan2
- RPRD1B | c.416-1G>C p.X139_splice | Splice Site (SNP) | VAF 25/94 reads (27%) | catalogued as COSV65032231; called by muse, mutect2, varscan2
- RYR2 | c.4409G>T p.G1470V | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV100769184, COSV63707161, COSV63719276; called by muse, mutect2, varscan2
- SDC2 | c.593A>G p.E198G | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56225583; called by muse, mutect2, varscan2
- SLC25A22 | c.136T>A p.Y46N | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100204289; called by muse, mutect2, varscan2
- SLC25A31 | c.261G>C p.L87F | Missense Mutation (SNP) | VAF 192/451 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV55417635, COSV99829221; called by muse, mutect2
- SPART | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 40/490 reads (8%) | catalogued as rs1390559187, COSV62086253; called by muse, mutect2
- SRGAP3 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64534262; called by muse, mutect2, varscan2
- TECTA | c.3134T>A p.L1045H | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV50687603, COSV50687648; called by muse, mutect2, varscan2
- TMEM223 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs756262183, COSV53667199, COSV53667300; called by muse, mutect2, varscan2
- TNS3 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs1210537225, COSV60786398; called by muse, mutect2, varscan2
- TP53 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as COSV52679151; called by muse, mutect2, varscan2
- TRAF3 | c.491A>T p.D164V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV61023630; called by muse, mutect2, varscan2
- TRPV6 | c.739C>G p.P247A | Missense Mutation (SNP) | VAF 22/365 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as COSV100844408; called by muse, mutect2
- TXNDC11 | c.917A>C p.H306P (on ENST00000356957 / NM_001303447.2; = p.H279P on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as COSV99031965, COSV99298283; called by muse, mutect2
- ULK1 | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as COSV100417193; called by muse, mutect2, varscan2
- UNC13C | c.2528A>G p.E843G | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.095); catalogued as COSV52840812; called by muse, mutect2, varscan2
- VCAM1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as rs779073619, COSV54117549; called by muse, mutect2, varscan2
- VPS13B | c.2869G>A p.D957N | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1215040847, COSV62132085; called by muse, mutect2, varscan2
- VSIG8 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV63652222; called by muse, mutect2, varscan2
- WASF1 | c.714-1G>T p.X238_splice | Splice Site (SNP) | VAF 39/143 reads (27%) | catalogued as COSV55617808; called by muse, mutect2, varscan2
- ZNF154 | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV70745581; called by muse, mutect2, varscan2
- ZNF417 | c.758T>C p.V253A | Missense Mutation (SNP) | VAF 63/504 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100364381; called by muse, mutect2, varscan2
- ZNF672 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV60637168; called by muse, mutect2, varscan2
- ATP2B4 | c.530del p.F177Sfs*50 | Frame Shift Del (DEL) | VAF 94/329 reads (29%) | called by mutect2, pindel, varscan2
- ACCSL | c.1695A>C p.A565= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as COSV66579888; called by muse, mutect2
- APOB | c.10944C>T p.V3648= | Silent (SNP) | VAF 37/223 reads (17%) | catalogued as rs370314131; ClinVar: likely benign; called by muse, mutect2, varscan2
- B4GALT1 | c.1170C>T p.I390= | Silent (SNP) | VAF 44/344 reads (13%) | catalogued as COSV101123008; called by muse, mutect2, varscan2
- CD109 | c.126G>T p.V42= | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as COSV54644800; called by muse, mutect2, varscan2
- CEP250 | c.4257G>A p.L1419= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as COSV61167957; called by muse, mutect2, varscan2
- GPR152 | c.1398C>T p.G466= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs748737778, COSV56888286; called by muse, mutect2, varscan2
- HBG2 | c.210T>G p.T70= | Silent (SNP) | VAF 62/630 reads (10%) | catalogued as rs768094911, COSV57963509, COSV57963783; called by muse, mutect2
- LAIR1 | c.804C>T p.S268= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV57305736; called by muse, mutect2, varscan2
- NECAB2 | c.519G>A p.T173= | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as rs139456465; called by muse, mutect2, varscan2
- OPRK1 | c.687C>T p.C229= | Silent (SNP) | VAF 20/164 reads (12%) | catalogued as rs201496681, COSV55568103; called by muse, mutect2, varscan2
- OR4D1 | c.90G>A p.L30= | Silent (SNP) | VAF 107/243 reads (44%) | catalogued as COSV52124351; called by muse, mutect2, varscan2
- RECK | c.2670C>T p.V890= | Silent (SNP) | VAF 59/222 reads (27%) | catalogued as rs752225712, COSV65034511; called by muse, mutect2, varscan2
- SCN4A | c.2091G>A p.V697= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as COSV71125483; called by muse, mutect2, varscan2
- SLITRK2 | c.1278C>G p.R426= | Silent (SNP) | VAF 44/96 reads (46%) | catalogued as COSV59422715; called by muse, mutect2, varscan2
- STEAP3 | c.75C>T p.P25= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV100713152, COSV61527654; called by muse, mutect2, varscan2
- UNC79 | c.3882C>T p.S1294= (on ENST00000393151 / NM_001346218.2; = p.S1117= on NM_020818.5) | Silent (SNP) | VAF 27/136 reads (20%) | catalogued as rs776961472, COSV56372293; called by muse, mutect2, varscan2
- UTRN | c.8472T>C p.H2824= | Silent (SNP) | VAF 40/244 reads (16%) | catalogued as COSV62306908; called by muse, mutect2, varscan2
- CCDC70 | c.-23C>T | 5'UTR (SNP) | VAF 36/93 reads (39%) | catalogued as rs760757110, COSV99665377; called by muse, mutect2, varscan2
- EPHA6 | c.2784+10213C>G | Intron (SNP) | VAF 30/273 reads (11%) | catalogued as COSV67557512; called by muse, mutect2
- TCF7L2 | c.1442+650C>T | Intron (SNP) | VAF 70/181 reads (39%) | catalogued as rs1422891742, COSV53336363, COSV53349319; called by muse, mutect2, varscan2
